Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0I9, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0I9-01A (Primary Tumor).

1CD-0-3

carcinoma, duct, infiltrating 8500/3

Site Code: breast, NOS C50.9

1/17/11

fw

Patient:

AP Surgical Pathology: Final.

Acc#

Surg Path

CLINICAL HISTORY:

Probable metastatic breast CA - year-old white female presenting with left femur fracture ? pathologic, has large 6 cm breast mass in left breast.

GROSS EXAMINATION:

A. "Left breast biopsy", in formalin. An irregular fragment of yellow fibro-adipose tissue measuring 5 x 2.5 x 2 cm in approximate dimensions. The specimen has previously been sectioned and a portion submitted for ER-PR evaluation. The margins of the specimen were not inked as the surgeon felt this was unnecessary. The specimen is sectioned and submitted in toto in Blocks A1 through A6.

DIAGNOSIS:

"LEFT BREAST BIOPSY":

1. INTRADUCTAL CARCINOMA, SOLID AND COMEDO-TYPES, AND INFILTRATING DUCT CARCINOMA (5 CM IN GREATEST DIMENSION), NSABP HISTOLOGIC GRADE 2 OF 3, NUCLEAR GRADE MODERATELY DIFFERENTIATED.

2. VASCULAR INVASION BY CARCINOMA IS IDENTIFIED.

Verified by:

(Electronic Signature)

Date Signed:-

HIFAA Discrepancy		X

Source: NCI Genomic Data Commons file 6bdd5fb7-200d-4406-b428-841580ae6d38 (TCGA-B6-A0I9.291884D2-FDFD-4C98-BA19-1A0824ABB68F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).